Somatic mutation profile of tumor specimen TCGA-BA-A8YP-01A (aliquot TCGA-BA-A8YP-01A-11D-A391-08) from TCGA case TCGA-BA-A8YP, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Oropharynx, NOS; AJCC pathologic stage: Stage IVB; Tumor grade: G2; Age at diagnosis: 50.3 years (18,355 days).
Specimen TCGA-BA-A8YP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4035a891-76f9-4dd4-ba48-e11c5cad5f94.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BA-A8YP-10A (Blood Derived Normal), aliquot TCGA-BA-A8YP-10A-01D-A394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7e3503b4-ea6c-4cb7-b164-95fdee6add7a

The open-access MAF lists 161 somatic variants for this specimen: 125 protein-altering or splice-affecting, 34 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 107, Silent 34, Nonsense Mutation 8, Splice Site 4, Frame Shift Del 2, Intron 1, In Frame Ins 1, RNA 1, In Frame Del 1, Nonstop Mutation 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGF12 | c.341G>A p.R114H (on ENST00000454309 / NM_021032.5; = p.R52H on NM_004113.6) | Missense Mutation (SNP) | VAF 60/184 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); catalogued as rs886039903, CM166790, COSV53173851; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1258T>C p.C420R | Missense Mutation (SNP) | VAF 36/138 reads (26%) | hotspot (GDC flag); SIFT tolerated (0.21); PolyPhen possibly damaging (0.908); catalogued as rs121913272, COSV55874020; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- PRRT2 | c.718C>T p.R240* | Nonsense Mutation (SNP) | VAF 6/32 reads (19%) | catalogued as rs387907126, CM1110412, COSV99569661; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.499C>T p.Q167* | Nonsense Mutation (SNP) | VAF 43/73 reads (59%) | hotspot (GDC flag); catalogued as rs1555526097, CM942118, COSV52735517, COSV53025177, COSV53136193, COSV53312374; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCF1 | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.052); catalogued as rs747137645, COSV100400890; called by muse, mutect2, varscan2
- ABLIM3 | c.1199G>A p.R400H | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.159); catalogued as rs747716272, COSV58641823; called by muse, mutect2, varscan2
- AGMAT | c.449C>T p.A150V | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.781); catalogued as COSV101011792; called by muse, mutect2
- AGO1 | c.752C>T p.S251F | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.076); catalogued as COSV100940865; called by muse, mutect2, varscan2
- AGO1 | c.2486C>T p.S829L | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.803); catalogued as rs747745215, COSV100940866; called by muse, varscan2
- AHNAK | c.7166C>T p.P2389L | Missense Mutation (SNP) | VAF 56/117 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99948054; called by muse, mutect2, varscan2
- ARHGAP32 | c.5522A>G p.H1841R (on ENST00000310343 / NM_001378025.1; = p.H1492R on NM_014715.4) | Missense Mutation (SNP) | VAF 67/116 reads (58%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.025); catalogued as rs753407271, COSV100088156; called by muse, mutect2, varscan2
- ARNT | c.103G>A p.A35T | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs201499435, COSV100591245; called by muse, mutect2, varscan2
- ATRN | c.2230T>C p.Y744H | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.125); catalogued as COSV99497356; called by muse, mutect2, varscan2
- BAALC | c.515G>A p.R172Q (on ENST00000297574 / NM_001364874.1; = p.R137Q on NM_024812.3) | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs781324772, COSV52562385; called by muse, mutect2, varscan2
- BIRC2 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 44/125 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV99926742; called by muse, mutect2, varscan2
- CA12 | c.542C>T p.P181L | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as rs1420074847, COSV99457879, COSV99458406; called by muse, mutect2
- CAMTA1 | c.1850T>C p.F617S | Missense Mutation (SNP) | VAF 40/195 reads (21%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.986); catalogued as COSV100350849; called by muse, mutect2, varscan2
- CATSPERD | c.1165-2A>G p.X389_splice | Splice Site (SNP) | VAF 26/132 reads (20%) | catalogued as COSV100486849; called by muse, mutect2, varscan2
- CCL4 | c.97G>A p.A33T | Missense Mutation (SNP) | VAF 46/75 reads (61%) | SIFT tolerated (0.08); PolyPhen benign (0.202); catalogued as rs751043350; called by muse, mutect2, varscan2
- CD5L | c.330A>C p.E110D | Missense Mutation (SNP) | VAF 42/226 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1422823723, COSV100941074; called by muse, mutect2, varscan2
- CHD8 | c.5668A>G p.I1890V (on ENST00000646647 / NM_001170629.2; = p.I1611V on NM_020920.4) | Missense Mutation (SNP) | VAF 65/83 reads (78%) | SIFT tolerated (0.17); PolyPhen benign (0.083); catalogued as rs1340891338, COSV100765325; called by muse, mutect2, varscan2
- CLIC6 | c.1910C>T p.T637M (on ENST00000360731 / NM_001317009.2; = p.T619M on NM_053277.3) | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs141470374; called by muse, mutect2, varscan2
- CLUH | c.3457G>A p.A1153T (on ENST00000435359; = p.A1192T on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV101425786; called by muse, mutect2
- COL5A3 | c.292G>A p.G98R | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.147); catalogued as COSV53422830; called by muse, mutect2, varscan2
- CPED1 | c.1195G>C p.E399Q | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.498); catalogued as COSV100120982, COSV60010187; called by muse, mutect2, varscan2
- CSMD3 | c.1655T>G p.L552R (on ENST00000297405 / NM_001363185.1; = p.L448R on NM_052900.3) | Missense Mutation (SNP) | VAF 21/135 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs563451721, COSV52120065, COSV99837776; called by muse, mutect2, varscan2
- CXCL6 | c.322G>A p.D108N | Missense Mutation (SNP) | VAF 32/122 reads (26%) | SIFT tolerated (0.52); PolyPhen benign (0.027); catalogued as COSV99884958; called by muse, mutect2, varscan2
- CYP2R1 | c.9G>T p.K3N | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.003); catalogued as rs782650289, COSV100584941; called by muse, mutect2, varscan2
- DCANP1 | c.139G>C p.E47Q | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.003); catalogued as COSV101538256, COSV72345828; called by muse, mutect2, varscan2
- DDX18 | c.1553G>C p.R518T | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as COSV54306308, COSV99604599; called by muse, varscan2
- DEFA3 | c.258G>T p.Q86H | Missense Mutation (SNP) | VAF 26/384 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.052); catalogued as rs1396030111; called by muse, mutect2
- DGKI | c.1007C>T p.A336V | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.039); catalogued as COSV99935436; called by muse, mutect2, varscan2
- DGKI | c.1006G>T p.A336S | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99935443; called by mutect2, varscan2
- DYNC2H1 | c.8216A>G p.Y2739C | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100518858; called by muse, mutect2, varscan2
- DZIP3 | c.1927G>A p.E643K | Missense Mutation (SNP) | VAF 31/127 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as COSV100847869; called by muse, mutect2, varscan2
- EDNRB | c.1598G>C p.*533Sext*18 (on ENST00000377211 / NM_001201397.1; = p.*443Sext*18 on NM_000115.5) | Nonstop Mutation (SNP) | VAF 25/56 reads (45%) | catalogued as COSV100526778; called by muse, mutect2, varscan2
- EFNB1 | c.961A>T p.S321C | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99214892; called by muse, mutect2
- EPHA7 | c.10C>G p.Q4E | Missense Mutation (SNP) | VAF 91/557 reads (16%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as rs202112730, COSV100992418, COSV100992419; called by muse, mutect2, varscan2
- EPRS1 | c.1743-1G>C p.X581_splice | Splice Site (SNP) | VAF 20/62 reads (32%) | catalogued as COSV100859412; called by muse, mutect2, varscan2
- FAM135B | c.1646C>T p.P549L | Missense Mutation (SNP) | VAF 45/136 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.084); catalogued as COSV99425000; called by muse, mutect2, varscan2
- FLACC1 | c.1291G>T p.D431Y | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.003); catalogued as COSV51845245, COSV99630396; called by muse, mutect2, varscan2
- FMO4 | c.809G>A p.G270E | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100882076; called by muse, mutect2, varscan2
- FNDC1 | c.3896G>A p.R1299H | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); catalogued as COSV51937601, COSV99033003; called by muse, mutect2, varscan2
- GRXCR2 | c.604G>A p.G202R | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100939995, COSV65061600; called by muse, mutect2, varscan2
- GSPT1 | c.542T>G p.L181R (on ENST00000420576 / NM_001130007.2; = p.L319R on NM_002094.4) | Missense Mutation (SNP) | VAF 21/181 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101341741; called by muse, mutect2, varscan2
- HAL | c.173G>T p.C58F | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.321); catalogued as COSV99701491; called by muse, mutect2
- HTR5A | c.739G>T p.E247* | Nonsense Mutation (SNP) | VAF 31/58 reads (53%) | catalogued as COSV99839791; called by muse, mutect2, varscan2
- IGHG1 | c.122G>A p.W41* | Nonsense Mutation (SNP) | VAF 23/34 reads (68%) | catalogued as rs1188633154; called by muse, mutect2, varscan2
- JRKL | c.327_329del p.F110del | In Frame Del (DEL) | VAF 80/164 reads (49%) | catalogued as rs746708322; called by pindel, varscan2
- KARS1 | c.1357G>A p.E453K | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56693273; called by muse, mutect2, varscan2
- KBTBD8 | c.1345G>T p.E449* | Nonsense Mutation (SNP) | VAF 21/40 reads (53%) | catalogued as COSV55129420, COSV55131764; called by muse, mutect2
- KIF2A | c.1295C>A p.S432* | Nonsense Mutation (SNP) | VAF 44/83 reads (53%) | catalogued as COSV101136520; called by muse, mutect2, varscan2
- KLHL14 | c.751G>T p.E251* | Nonsense Mutation (SNP) | VAF 8/60 reads (13%) | catalogued as COSV100809047; called by muse, mutect2, varscan2
- KLK8 | c.201G>A p.W67* | Nonsense Mutation (SNP) | VAF 33/219 reads (15%) | catalogued as COSV99144009; called by muse, mutect2, varscan2
- LILRB3 | c.133G>A p.V45M | Missense Mutation (SNP) | VAF 77/309 reads (25%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.892); catalogued as rs746656873; called by muse, mutect2, varscan2
- LONP1 | c.239C>T p.S80L | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.038); catalogued as rs781065201, COSV62261893; called by muse, mutect2
- LRP1B | c.11554G>C p.G3852R | Missense Mutation (SNP) | VAF 35/111 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV101257889, COSV67277956; called by muse, mutect2, varscan2
- LRRC10 | c.194A>G p.N65S | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs773514906, COSV100825501; called by muse, mutect2, varscan2
- MCM9 | c.66G>C p.K22N | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV100285007; called by muse, mutect2, varscan2
- MDN1 | c.5405A>T p.E1802V | Missense Mutation (SNP) | VAF 39/85 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); catalogued as COSV101021497; called by muse, mutect2, varscan2
- MED12L | c.1763A>G p.N588S | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT tolerated (0.67); PolyPhen benign (0.007); catalogued as COSV99853638; called by muse, mutect2
- MPHOSPH9 | c.2130C>G p.I710M | Missense Mutation (SNP) | VAF 22/33 reads (67%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); catalogued as COSV100186901; called by muse, mutect2, varscan2
- NFASC | c.2593T>C p.F865L (on ENST00000339876 / NM_001378329.1; = p.F968L on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/166 reads (29%) | SIFT tolerated (0.65); PolyPhen benign (0.101); catalogued as COSV100364415; called by muse, mutect2, varscan2
- NLRP11 | c.169C>A p.P57T | Missense Mutation (SNP) | VAF 21/140 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as COSV100789764, COSV64087595; called by muse, mutect2, varscan2
- OBSCN | c.6112G>A p.E2038K | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.012); catalogued as COSV52735572; called by muse, mutect2, varscan2
- OR4N2 | c.514A>C p.N172H | Missense Mutation (SNP) | VAF 55/346 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV100269714; called by muse, mutect2, varscan2
- P4HA1 | c.659A>G p.D220G | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.184); catalogued as COSV99696986; called by muse, mutect2, varscan2
- PCDH15 | c.313A>G p.R105G | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100222530; called by muse, mutect2, varscan2
- PCDHA12 | c.1706C>T p.P569L | Missense Mutation (SNP) | VAF 123/203 reads (61%) | SIFT tolerated, low confidence (0.84); PolyPhen benign (0); catalogued as COSV56497769; called by muse, mutect2, varscan2
- PEG3 | c.1951A>G p.R651G | Missense Mutation (SNP) | VAF 92/172 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as COSV99689375; called by muse, mutect2, varscan2
- PIK3CA | c.1252G>A p.E418K | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.904); catalogued as rs397517199, COSV104381248, COSV55880235, COSV55880477; ClinVar: uncertain significance; called by muse, varscan2
- PIWIL3 | c.398G>A p.R133Q | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.125); catalogued as rs1050887678, COSV100177508; called by muse, mutect2
- PLCB3 | c.2476C>T p.R826W | Missense Mutation (SNP) | VAF 19/140 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54190691; called by muse, mutect2, varscan2
- PLEKHH2 | c.497T>C p.L166P | Missense Mutation (SNP) | VAF 82/89 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV99174842; called by muse, mutect2, varscan2
- PLPP4 | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.27); catalogued as rs754384871, COSV100956381; called by muse, mutect2, varscan2
- PLPPR2 | c.371G>A p.R124Q | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV99264481; called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.1835T>C p.L612P | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.936); catalogued as COSV99461438; called by muse, mutect2, varscan2
- PPP1R3A | c.410T>G p.L137R | Missense Mutation (SNP) | VAF 19/208 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV99493245, COSV99493732; called by muse, mutect2
- PRKAG3 | c.1190C>T p.S397F | Missense Mutation (SNP) | VAF 48/72 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99291997; called by muse, mutect2, varscan2
- PRKCG | c.1705G>A p.E569K | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.798); catalogued as COSV54724979; called by muse, mutect2, varscan2
- PRKD2 | c.1466C>G p.P489R | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); catalogued as COSV99354382; called by muse, mutect2, varscan2
- PRPF6 | c.944C>T p.S315L | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as COSV99412232; called by muse, mutect2, varscan2
- PSMB9 | c.385G>T p.G129C | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100841237; called by muse, mutect2, varscan2
- PSPC1 | c.1259C>T p.P420L | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.098); catalogued as COSV100142420; called by muse, mutect2
- R3HCC1L | c.719G>A p.S240N | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.48); PolyPhen benign (0.012); catalogued as COSV100107398; called by muse, mutect2, varscan2
- RANBP6 | c.543C>G p.I181M | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); catalogued as COSV99424227; called by muse, mutect2, varscan2
- RASGRP2 | c.1733C>T p.S578F | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.496); catalogued as rs1436301579, COSV100818284; called by muse, mutect2
- RIOK3 | c.179+1G>A p.X60_splice | Splice Site (SNP) | VAF 21/143 reads (15%) | catalogued as rs373422920; called by muse, mutect2, varscan2
- ROCK2 | c.526G>A p.D176N | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99837595; called by muse, mutect2, varscan2
- RTKN | c.776T>G p.L259W (on ENST00000272430 / NM_001015055.2; = p.L246W on NM_033046.2) | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99269698; called by muse, mutect2, varscan2
- SERTAD2 | c.371C>T p.T124M | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.025); catalogued as rs199521891, COSV100512216; called by muse, mutect2, varscan2
- SETD5 | c.343G>A p.G115R | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.413); catalogued as COSV100200803; called by muse, mutect2
- SLC27A4 | c.1858G>A p.A620T | Missense Mutation (SNP) | VAF 36/122 reads (30%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV100307387; called by muse, mutect2, varscan2
- SMYD3 | c.841C>A p.Q281K (on ENST00000490107 / NM_001375962.1; = p.Q222K on NM_022743.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs1198985796, COSV100830777; called by muse, mutect2, varscan2
- SPG11 | c.3926A>C p.K1309T | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.215); catalogued as COSV99968958; called by muse, mutect2, varscan2
- SRRT | c.184C>T p.R62W | Missense Mutation (SNP) | VAF 58/208 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.63); catalogued as rs748518284, COSV100730197; called by muse, mutect2, varscan2
- STEAP1 | c.340A>G p.I114V | Missense Mutation (SNP) | VAF 18/184 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99787685; called by muse, varscan2
- SYNE4 | c.402G>C p.Q134H | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV99431149; called by muse, mutect2
- TASOR2 | c.2171C>T p.S724F | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); catalogued as COSV60165430, COSV60168631; called by muse, mutect2, varscan2
- TECTA | c.3317G>A p.G1106D | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.918); catalogued as rs144844263; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TFIP11 | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 73/116 reads (63%) | SIFT tolerated (0.33); PolyPhen benign (0.371); catalogued as COSV101316475; called by muse, mutect2, varscan2
- TNFSF13B | c.526A>T p.S176C | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.738); catalogued as COSV101022372; called by muse, mutect2, varscan2
- TNPO1 | c.247A>C p.N83H | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.847); catalogued as COSV100473638; called by muse, mutect2, varscan2
- TRIM42 | c.936C>A p.F312L | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV99648480; called by muse, mutect2, varscan2
- UBA1 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 10/33 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.456); catalogued as COSV100255802; called by muse, mutect2, varscan2
- UBA1 | c.170G>A p.R57Q | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1556786560, COSV100255804; called by muse, mutect2, varscan2
- UBQLNL | c.429A>C p.Q143H | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV100974286, COSV100974659; called by muse, mutect2, varscan2
- UFL1 | c.187A>G p.S63G | Missense Mutation (SNP) | VAF 27/126 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.173); catalogued as COSV100990088; called by muse, mutect2, varscan2
- WWC1 | c.2096G>A p.R699H | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs148388652; called by muse, mutect2, varscan2
- YEATS2 | c.1391-1G>T p.X464_splice | Splice Site (SNP) | VAF 19/242 reads (8%) | catalogued as COSV100527933; called by muse, mutect2
- YIPF7 | c.102T>G p.D34E | Missense Mutation (SNP) | VAF 8/10 reads (80%) | SIFT deleterious (0.05); PolyPhen benign (0.066); catalogued as COSV100274543; called by muse, mutect2, varscan2
- ZDBF2 | c.6948G>T p.Q2316H | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.037); catalogued as COSV100985046; called by muse, mutect2, varscan2
- ZFP41 | c.562C>T p.R188C | Missense Mutation (SNP) | VAF 37/203 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.332); catalogued as rs533687952, COSV58087669; called by muse, mutect2, varscan2
- ZFPL1 | c.849G>T p.M283I | Missense Mutation (SNP) | VAF 36/159 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as COSV99297884; called by muse, mutect2, varscan2
- ZMYM4 | c.1342C>A p.Q448K | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.6); PolyPhen benign (0.007); catalogued as COSV100110756; called by muse, mutect2, varscan2
- ZNF257 | c.1019G>C p.G340A | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.111); catalogued as COSV71306361; called by muse, mutect2, varscan2
- ZNF385B | c.265G>T p.A89S | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as rs544716600, COSV101343136, COSV69800485; called by muse, mutect2, varscan2
- ZNF44 | c.458G>A p.S153N (on ENST00000356109 / NM_001164276.2; = p.S105N on NM_016264.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.017); catalogued as COSV100633596; called by muse, mutect2, varscan2
- ZNF547 | c.94C>G p.Q32E | Missense Mutation (SNP) | VAF 76/439 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs781348428, COSV99988008; called by muse, mutect2, varscan2
- ZNF599 | c.407G>T p.R136M | Missense Mutation (SNP) | VAF 35/196 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as COSV100251178; called by muse, mutect2, varscan2
- C17orf98 | c.275G>A p.R92K | Missense Mutation (SNP) | VAF 86/129 reads (67%) | SIFT tolerated (0.46); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- NUMA1 | c.3698_3700dup p.E1233dup | In Frame Ins (INS) | VAF 22/120 reads (18%) | called by mutect2, varscan2
- STAB2 | c.4859_4869del p.F1620Sfs*18 | Frame Shift Del (DEL) | VAF 40/192 reads (21%) | called by mutect2, pindel, varscan2
- TMEM94 | c.4013_4019del p.Y1338Cfs*13 | Frame Shift Del (DEL) | VAF 75/106 reads (71%) | called by mutect2, pindel, varscan2
- TRAV21 | c.251C>G p.S84W | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT tolerated (0.05); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- ABCC6 | c.1482C>A p.I494= | Silent (SNP) | VAF 74/137 reads (54%) | catalogued as COSV99229012, COSV99229290; called by muse, mutect2, varscan2
- ACAD9 | c.1611C>T p.L537= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as COSV100459258; called by muse, mutect2, varscan2
- AK9 | c.5580G>A p.K1860= | Silent (SNP) | VAF 22/70 reads (31%) | catalogued as rs1007945150, COSV101413976; called by muse, mutect2, varscan2
- ARFGAP1 | c.619C>T p.L207= | Silent (SNP) | VAF 14/65 reads (22%) | catalogued as COSV100796690; called by muse, mutect2, varscan2
- C1QL2 | c.645C>T p.D215= | Silent (SNP) | VAF 26/82 reads (32%) | catalogued as rs371906170; called by muse, mutect2, varscan2
- COL6A6 | c.6018T>A p.T2006= | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as COSV100650422; called by muse, mutect2, varscan2
- COPA | c.3393C>G p.L1131= | Silent (SNP) | VAF 40/123 reads (33%) | catalogued as COSV99616005; called by muse, mutect2, varscan2
- CPVL | c.1368G>C p.L456= | Silent (SNP) | VAF 26/103 reads (25%) | catalogued as COSV99606012; called by muse, mutect2, varscan2
- DST | c.13791G>A p.Q4597= (on ENST00000361203 / NM_001374722.1; = p.Q2185= on NM_015548.5) | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV99757491; called by muse, mutect2, varscan2
- EMX2 | c.741C>T p.D247= | Silent (SNP) | VAF 13/20 reads (65%) | catalogued as rs776602753, COSV101463619; called by muse, mutect2, varscan2
- ENAM | c.2988C>T p.N996= | Silent (SNP) | VAF 36/173 reads (21%) | catalogued as COSV101253160; called by muse, mutect2, varscan2
- ERCC6L2 | c.4542G>A p.R1514= | Silent (SNP) | VAF 25/82 reads (30%) | catalogued as rs369255194; called by muse, mutect2, varscan2
- FANCB | c.741C>T p.I247= | Silent (SNP) | VAF 16/32 reads (50%) | catalogued as COSV100146599; called by muse, mutect2, varscan2
- FLNC | c.1095G>A p.E365= | Silent (SNP) | VAF 29/104 reads (28%) | catalogued as COSV100368280; called by muse, mutect2, varscan2
- LRRC7 | c.207C>T p.H69= (on ENST00000651989 / NM_001370785.2; = p.H36= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 11/57 reads (19%) | catalogued as rs777252937, COSV99227761; called by muse, mutect2, varscan2
- LRRK2 | c.7323T>A p.T2441= | Silent (SNP) | VAF 13/64 reads (20%) | catalogued as rs558176427, COSV54151298; called by muse, mutect2, varscan2
- LZTR1 | c.1836C>A p.I612= | Silent (SNP) | VAF 19/147 reads (13%) | catalogued as COSV99301933; called by muse, mutect2, varscan2
- MAP4 | c.2067G>A p.P689= | Silent (SNP) | VAF 27/49 reads (55%) | catalogued as COSV99275638; called by muse, mutect2, varscan2
- MEN1 | c.1407G>A p.A469= | Silent (SNP) | VAF 15/81 reads (19%) | catalogued as rs754445482, CD035819, COSV99580505; ClinVar: likely benign; called by muse, mutect2, varscan2
- MSR1 | c.768G>A p.L256= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV100027495; called by muse, mutect2, varscan2
- NAB1 | c.246C>T p.F82= | Silent (SNP) | VAF 85/156 reads (54%) | catalogued as COSV100493053; called by muse, mutect2, varscan2
- OR10W1 | c.465C>T p.F155= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as COSV101223697; called by muse, mutect2, varscan2
- PHF21A | c.1194G>A p.P398= (on ENST00000418153 / NM_001101802.3; = p.P399= on NM_016621.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 23/146 reads (16%) | catalogued as rs768776752, COSV99138729; called by muse, mutect2, varscan2
- RELN | c.3927T>C p.C1309= | Silent (SNP) | VAF 75/96 reads (78%) | catalogued as COSV100634050; called by muse, mutect2, varscan2
- SEC14L5 | c.1491G>A p.E497= | Silent (SNP) | VAF 35/63 reads (56%) | catalogued as COSV52038062, COSV99229038; called by muse, mutect2, varscan2
- SEPTIN12 | c.543G>A p.Q181= | Silent (SNP) | VAF 34/53 reads (64%) | catalogued as COSV99190802; called by muse, mutect2, varscan2
- SLC2A10 | c.1452G>C p.L484= | Silent (SNP) | VAF 26/89 reads (29%) | catalogued as COSV100826377; called by muse, mutect2, varscan2
- TLR4 | c.1752T>G p.T584= (on ENST00000355622 / NM_138554.5; = p.T544= on NM_003266.4) | Silent (SNP) | VAF 21/68 reads (31%) | catalogued as COSV62922767; called by muse, mutect2, varscan2
- TM9SF2 | c.129C>A p.P43= | Silent (SNP) | VAF 20/81 reads (25%) | catalogued as rs755254521, COSV100816411, COSV63480844, COSV63480861; called by muse, mutect2, varscan2
- TMEM63A | c.2211A>G p.K737= | Silent (SNP) | VAF 25/55 reads (45%) | catalogued as COSV99689058; called by muse, mutect2, varscan2
- TRIM42 | c.2046C>T p.I682= | Silent (SNP) | VAF 31/169 reads (18%) | catalogued as COSV99648481; called by muse, mutect2, varscan2
- WDFY3 | c.2766C>T p.P922= | Silent (SNP) | VAF 15/63 reads (24%) | catalogued as rs769778963, COSV99884084; called by muse, mutect2, varscan2
- ZNF280D | c.2661A>G p.A887= | Silent (SNP) | VAF 51/87 reads (59%) | catalogued as rs1382495004, COSV99974666; called by muse, mutect2, varscan2
- ZNF649 | c.675G>A p.E225= | Silent (SNP) | VAF 19/151 reads (13%) | catalogued as COSV100031116, COSV56817787; called by muse, mutect2, varscan2
- DST | c.4296+4988G>C | Intron (SNP) | VAF 17/89 reads (19%) | catalogued as COSV99757492; called by muse, mutect2, varscan2
- FOLH1B | n.1951T>C | RNA (SNP) | VAF 80/148 reads (54%) | called by muse, mutect2, varscan2
